TCGA case TCGA-Z4-A8JB — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de0cfb5d-0db6-4bf9-8a92-c5de4208bb04

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 24 years; Vital status: Alive.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 25.0 years (9,123 days); Year of diagnosis: 2013; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.8; Tumor length measurement: 9; Tumor width measurement: 5.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Deep.

Follow-up (2 entries)
- Days to follow up: 56 days; Disease response: Tumor Free.
- Days to follow up: 133 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Z4-A8JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-Z4-A8JB-01A-02-TS2: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-Z4-A8JB-01A-03-TS3: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-Z4-A8JB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Z4-A8JB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Desmoid Tumor; Margin status: Negative; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 9.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 133 days; disease-specific survival: no event (censored), 133 days; disease-free interval: no event (censored), 133 days; progression-free interval: no event (censored), 133 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Z4-A8JB-01A-23D-A37B-01): tumor purity 0.51, ploidy 1.98, whole-genome doublings 0.
